Somatic mutation profile of tumor specimen TCGA-CQ-5333-01A (aliquot TCGA-CQ-5333-01A-01D-2394-08) from TCGA case TCGA-CQ-5333, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 74.2 years (27,110 days).
Specimen TCGA-CQ-5333-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60c1b98e-2876-489c-a9a1-f64e1b28b91c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5333-10A (Blood Derived Normal), aliquot TCGA-CQ-5333-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad93bea8-2e8d-4d7e-ba19-b52f2f99c688

The open-access MAF lists 217 somatic variants for this specimen: 161 protein-altering or splice-affecting, 54 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 54, Nonsense Mutation 20, Splice Site 2, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2B | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs1057519283, COSV99385902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1367G>A p.C456Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622058, CM159416, COSV53046494, COSV53053704; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, varscan2
- AC004922.1 | c.1779G>A p.A593= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs779597975, COSV99402992; called by muse, mutect2, varscan2
- ACTB | c.1043C>G p.S348W | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV59317066, COSV59317805; called by muse, varscan2
- ADAMTS5 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as COSV99537948; called by muse, mutect2, varscan2
- ADAMTS8 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99961245; called by muse, mutect2, varscan2
- AHNAK | c.7204G>C p.G2402R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99948458; called by muse, mutect2, varscan2
- AMDHD2 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99565987; called by muse, mutect2, varscan2
- ANGPT2 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 41/258 reads (16%) | catalogued as rs752903054, COSV57336274; called by muse, mutect2, varscan2
- ARHGAP24 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs371691470; called by muse, mutect2, varscan2
- ARHGAP31 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV99957367; called by muse, mutect2, varscan2
- ASCC3 | c.2921G>C p.G974A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100226031; called by muse, mutect2, varscan2
- ASPH | c.1034T>A p.L345H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101064102; called by muse, mutect2, varscan2
- ATP13A4 | c.1114G>T p.G372* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV55068864, COSV99794861; called by muse, mutect2, varscan2
- ATP8A1 | c.1828G>C p.A610P | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100046682; called by muse, mutect2
- ATP8A2 | c.2343C>A p.F781L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99682963; called by muse, mutect2, varscan2
- ATRNL1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100746433; called by muse, mutect2, varscan2
- BCKDK | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1347210745, COSV54890351; called by muse, mutect2, varscan2
- BCL6 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV99215856; called by muse, mutect2, varscan2
- BRD1 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99350001; called by muse, mutect2, varscan2
- C16orf89 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs781114875, COSV60124626; called by muse, mutect2, varscan2
- C1orf174 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV100851806; called by muse, mutect2, varscan2
- CASP8 | c.803-1G>C p.X268_splice (on ENST00000432109 / NM_033355.3; = p.X285_splice on NM_001228.4) | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99630456; called by muse, mutect2, varscan2
- CASP8 | c.1393C>T p.Q465* (on ENST00000432109 / NM_033355.3; = p.Q482* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV51844901; called by muse, mutect2, varscan2
- CCR3 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100656631; called by muse, mutect2, varscan2
- CECR2 | c.2467C>T p.R823C (on ENST00000342247 / NM_001290047.2; = p.R640C on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs771332466, COSV52841317; called by mutect2, varscan2
- CEP192 | c.7160C>G p.S2387C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs1329526468, COSV100381614, COSV58060374; called by muse, mutect2, varscan2
- CLTCL1 | c.3289G>C p.E1097Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99595433; called by muse, mutect2
- COG2 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100794727, COSV64187426; called by muse, mutect2, varscan2
- COL17A1 | c.2813C>G p.S938* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100793245; called by muse, mutect2, varscan2
- COL6A1 | c.2369A>G p.K790R | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.018); catalogued as COSV100720329; called by muse, mutect2, varscan2
- CPAMD8 | c.781G>A p.A261T (on ENST00000651564; = p.A214T on NM_015692.5) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767087866, COSV99359563; called by muse, mutect2, varscan2
- CRAT | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as rs760934837, COSV100540055; called by muse, mutect2, varscan2
- CREBBP | c.3046G>T p.E1016* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV99270884; called by muse, mutect2, varscan2
- CRY1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99150555, COSV99151019; called by muse, mutect2, varscan2
- CSMD3 | c.4522G>A p.D1508N (on ENST00000297405 / NM_001363185.1; = p.D1404N on NM_052900.3) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV52219365, COSV99840016; called by muse, mutect2, varscan2
- CTCF | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50504119; called by muse, mutect2
- CTNNA2 | c.2126A>G p.N709S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100561375; called by muse, mutect2, varscan2
- CYP4A11 | c.825G>C p.Q275H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100152499; called by muse, mutect2, varscan2
- CYP4A11 | c.785A>C p.H262P | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100152502; called by muse, mutect2, varscan2
- DCAF12L1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV64421619; called by muse, mutect2, varscan2
- DMPK | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99353410; called by muse, mutect2, varscan2
- DSPP | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.035); catalogued as COSV99217634; called by muse, mutect2, varscan2
- DYNC1H1 | c.4862G>C p.R1621T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100795108, COSV64138253; called by muse, mutect2, varscan2
- DYSF | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.146); catalogued as rs761906797, COSV50274317, COSV99248848; called by mutect2, varscan2
- EEF2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs946697377, COSV100500843; called by muse, mutect2, varscan2
- EFCAB7 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs909343303, COSV100391328; called by muse, mutect2
- ETAA1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99712866; called by muse, mutect2, varscan2
- ETV5 | c.607A>G p.M203V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV100112446; called by muse, mutect2, varscan2
- FAM193B | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100286692; called by mutect2, varscan2
- FEZF1 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs527670913, COSV100484520; called by muse, mutect2
- FLG2 | c.5051C>A p.S1684* | Nonsense Mutation (SNP) | VAF 56/411 reads (14%) | catalogued as COSV101166030, COSV66170966; called by muse, mutect2, varscan2
- FREM2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as rs747164291, COSV54827782; called by muse, mutect2, varscan2
- GABRA5 | c.824C>G p.S275* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100164730, COSV100165458, COSV59485927; called by muse, mutect2, varscan2
- GFM2 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57190365, COSV99714526; called by muse, mutect2
- GMDS | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101070603; called by muse, mutect2, varscan2
- GTDC1 | c.1319C>A p.A440E (on ENST00000344850 / NM_001354361.1; = p.A355E on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99601133; called by muse, mutect2, varscan2
- GUCY2D | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99644118; called by muse, mutect2, varscan2
- HELB | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144350290; called by muse, mutect2, varscan2
- HINFP | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1428459708, COSV100640865, COSV63432693; called by muse, mutect2, varscan2
- HIPK2 | c.3259C>G p.L1087V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV101301650; called by muse, mutect2, varscan2
- HK3 | c.2675G>A p.C892Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1433669510, COSV99458899; called by muse, mutect2, varscan2
- HK3 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV99458900; called by muse, mutect2, varscan2
- HLA-DQB1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs9273626, COSV100891308; called by muse, mutect2
- HTR6 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV99230324; called by muse, mutect2, varscan2
- IBTK | c.3517A>T p.N1173Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100091074; called by muse, mutect2
- IL1RL2 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV99960883; called by muse, mutect2, varscan2
- KCNMB2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV100843990; called by muse, mutect2, varscan2
- KIAA0319L | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100357507, COSV57845208; called by muse, mutect2, varscan2
- KRTAP13-2 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV101299654; called by muse, mutect2, varscan2
- LAMB2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs754919265, COSV100565350; called by muse, mutect2, varscan2
- LAMC1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs1317787761, COSV99280041; called by muse, varscan2
- LIFR | c.3263C>A p.T1088K | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV99664809; called by muse, mutect2, varscan2
- LPL | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100255681; called by muse, mutect2, varscan2
- LRRC15 | c.1529G>A p.S510N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs1214618007, COSV100752806; called by muse, mutect2, varscan2
- MAP3K12 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.375); catalogued as rs745858800, COSV57230978; called by muse, mutect2, varscan2
- MAP3K6 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1418982398, COSV100709313; called by muse, mutect2, varscan2
- MDP1 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164585, COSV99164643; called by muse, mutect2
- MED16 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.503); catalogued as COSV99515961; called by muse, mutect2, varscan2
- MFAP1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV51039432; called by muse, mutect2, varscan2
- MICAL3 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as COSV99262248; called by muse, mutect2, varscan2
- MKX | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1277048456, COSV101008824; called by muse, mutect2
- MMAA | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV99849954; called by muse, mutect2, varscan2
- MRPL4 | c.172C>G p.H58D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV99459976; called by muse, mutect2
- MUC4 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100641123, COSV62182501; called by muse, mutect2, varscan2
- MYH3 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV56860349, COSV56864570; called by muse, mutect2
- NCAM1 | c.2059G>A p.E687K (on ENST00000316851 / NM_181351.5; = p.E677K on NM_000615.7) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57521907; called by muse, mutect2, varscan2
- NCF2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as COSV100838916; called by muse, mutect2
- NDUFV3 | c.56T>A p.L19H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV100447064; called by muse, mutect2, varscan2
- NKRF | c.1126T>G p.W376G | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100441766; called by muse, mutect2, varscan2
- NUTM1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100149106; called by muse, mutect2, varscan2
- OPRM1 | c.995G>A p.C332Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV57688214; called by muse, mutect2, varscan2
- OR14I1 | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV100700507; called by muse, mutect2
- OR2T2 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100737728, COSV61618049, COSV61618167; called by muse, mutect2
- P2RY2 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100232794, COSV60776254; called by muse, mutect2, varscan2
- PCDH17 | c.2833C>T p.R945* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs1474507050, COSV100931771; called by muse, mutect2, varscan2
- PCDHAC1 | c.1768A>T p.S590C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99167335; called by muse, mutect2, varscan2
- PCOLCE | c.810C>A p.Y270* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99775274; called by muse, mutect2, varscan2
- PDE7B | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV100367959; called by muse, mutect2, varscan2
- PENK | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs767183741, COSV59240542; called by muse, mutect2, varscan2
- PES1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as COSV100073227; called by muse, mutect2, varscan2
- PKP4 | c.2566G>C p.G856R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100733904; called by muse, mutect2, varscan2
- PLAG1 | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100388037; called by muse, mutect2, varscan2
- PLBD1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749862513, COSV53692958; called by muse, mutect2, varscan2
- PPIP5K2 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100383999; called by muse, mutect2
- PRKAG3 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99292036; called by muse, mutect2
- PTPRG | c.2890T>C p.Y964H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99875929; called by muse, mutect2, varscan2
- RAI1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV99884536; called by muse, mutect2, varscan2
- RARG | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100553574; called by muse, mutect2
- RFX7 | c.467A>G p.Y156C (on ENST00000559447 / NM_001368074.1; = p.Y253C on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1258184198, COSV100429056; called by muse, mutect2
- RHOV | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.026); catalogued as COSV55028128, COSV99592121; called by muse, mutect2
- RUNX2 | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767577; called by muse, mutect2, varscan2
- RXFP1 | c.1427C>A p.A476E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs530687587, COSV100313965, COSV57046034; called by muse, mutect2, varscan2
- RYR2 | c.6933G>C p.E2311D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM024368, COSV100771852; called by muse, mutect2
- SAMHD1 | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99484183; called by muse, mutect2, varscan2
- SBNO2 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100684775; called by muse, mutect2
- SCN1A | c.4564C>G p.P1522A (on ENST00000303395 / NM_001202435.3; = p.P1511A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100321165; called by muse, mutect2, varscan2
- SDK1 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs781675538, COSV101269598; called by muse, mutect2, varscan2
- SEC14L5 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369407626; called by muse, mutect2, varscan2
- SGSM1 | c.1072C>A p.H358N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101240916; called by muse, mutect2, varscan2
- SLC44A3 | c.903G>C p.L301F (on ENST00000271227 / NM_001114106.3; = p.L253F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1028683054, COSV54729395, COSV99598398; called by muse, mutect2, varscan2
- SLC5A10 | c.1334C>T p.S445L (on ENST00000395645 / NM_001042450.4; = p.S461L on NM_152351.5) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99408239; called by muse, mutect2, varscan2
- SLC7A1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs755374847, COSV66330425; called by muse, mutect2, varscan2
- SMC2 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV99659321; called by muse, mutect2, varscan2
- SSH3 | c.1034C>A p.A345E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1368400269, COSV100354663; called by muse, mutect2, varscan2
- ST8SIA5 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | PolyPhen benign (0.438); catalogued as COSV100164813; called by muse, mutect2, varscan2
- STAC | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV56208118, COSV99830320; called by muse, mutect2, varscan2
- STOML2 | c.427_428del p.L143Gfs*23 | Frame Shift Del (DEL) | VAF 34/231 reads (15%) | catalogued as rs1564008198; called by pindel, varscan2
- STOML3 | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV101105354; called by muse, mutect2, varscan2
- SYNE1 | c.18908A>G p.H6303R (on ENST00000367255 / NM_182961.4; = p.H6232R on NM_033071.3) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99571698; called by muse, mutect2, varscan2
- TAF1B | c.1340G>C p.R447T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99722302; called by muse, mutect2, varscan2
- TBC1D10A | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99304757; called by muse, mutect2, varscan2
- TEX44 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV100009809; called by muse, mutect2, varscan2
- THAP2 | c.249T>G p.C83W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100350533; called by muse, mutect2, varscan2
- TMEM161B | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99680643; called by muse, mutect2, varscan2
- TMEM40 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV99277195; called by muse, mutect2
- TMTC3 | c.2318G>T p.G773V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99898509; called by muse, mutect2, varscan2
- TOX3 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99567843; called by muse, mutect2, varscan2
- TPD52L2 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1235049244, COSV99410784; called by muse, mutect2, varscan2
- TREML1 | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1384198061, COSV100632650; called by muse, mutect2, varscan2
- TRMT2B | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs761129882, COSV100105538; called by muse, mutect2, varscan2
- TSPAN18 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100370931; called by muse, mutect2, varscan2
- UGT1A10 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 131/468 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149598882; called by muse, mutect2, varscan2
- URI1 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs149845017; called by muse, mutect2, varscan2
- UTP11 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV100884944; called by muse, mutect2
- UTP11 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.71); catalogued as COSV100884946; called by muse, mutect2, varscan2
- VNN3 | c.213+2T>A p.X71_splice | Splice Site (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99258453; called by muse, mutect2
- VPS13C | c.5398C>G p.L1800V (on ENST00000644861 / NM_020821.3; = p.L1757V on NM_017684.5) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV99829296; called by muse, mutect2, varscan2
- WASF2 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101420806; called by muse, mutect2, varscan2
- WNT8B | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as COSV100649059; called by muse, mutect2, varscan2
- ZDHHC15 | c.370G>T p.G124* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100973813; called by muse, mutect2, varscan2
- ZNF212 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV100242403; called by muse, mutect2, varscan2
- ZNF518B | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV100456789; called by muse, mutect2
- ZNF700 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.815); catalogued as COSV99583664; called by muse, mutect2, varscan2
- ZNF808 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1430906684, COSV100708078, COSV63119025; called by muse, mutect2, varscan2
- ZNF99 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV101233886; called by muse, mutect2
- KMT2A | c.5855_5869del p.S1952_F1956del | In Frame Del (DEL) | VAF 46/342 reads (13%) | called by mutect2, pindel
- MCM8 | c.2490del p.G831Afs*17 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- PCLO | c.5418dup p.S1807Ifs*7 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | called by mutect2, pindel
- ABCC1 | c.1437C>A p.V479= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100579941; called by muse, mutect2, varscan2
- ACSL5 | c.1293C>T p.F431= (on ENST00000354273; = p.F487= on NM_016234.3) | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100634691; called by muse, mutect2, varscan2
- ADAMTS20 | c.5406C>T p.F1802= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV101239754; called by muse, mutect2, varscan2
- AFF3 | c.315G>A p.V105= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100419559; called by muse, mutect2, varscan2
- ARFGAP3 | c.1521G>A p.V507= | Silent (SNP) | VAF 32/250 reads (13%) | catalogued as COSV99605407; called by muse, mutect2, varscan2
- ARID3B | c.123G>A p.L41= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs767113498, COSV60558976; called by muse, mutect2, varscan2
- ATP10A | c.4083C>A p.V1361= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs1290639295, COSV100791387; called by muse, mutect2
- BSX | c.666C>T p.D222= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1449668356, COSV100545268; called by muse, mutect2, varscan2
- CDH13 | c.831C>T p.T277= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs542715718, COSV99227975; called by muse, mutect2, varscan2
- CDH4 | c.2295G>A p.T765= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs761908460, COSV64640909; called by muse, mutect2, varscan2
- CHST14 | c.783C>G p.P261= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as COSV100087014; called by muse, mutect2, varscan2
- CHST6 | c.564C>G p.L188= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV59999959, COSV60002189; called by muse, mutect2, varscan2
- CIRBP | c.435G>A p.R145= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100309837; called by muse, mutect2, varscan2
- CSGALNACT1 | c.990G>A p.L330= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV100174556; called by muse, mutect2, varscan2
- CUX2 | c.1131G>T p.L377= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV99920142; called by muse, mutect2, varscan2
- DIXDC1 | c.225C>T p.P75= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs781839566, COSV101098734, COSV101098870; called by muse, mutect2, varscan2
- EEF2 | c.357C>G p.L119= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs905393985, COSV100500842; called by muse, mutect2, varscan2
- FAM118A | c.750C>T p.S250= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as rs377185744; called by muse, mutect2, varscan2
- FFAR4 | c.924C>T p.F308= | Silent (SNP) | VAF 40/239 reads (17%) | catalogued as COSV101012284; called by muse, mutect2, varscan2
- FOXD4 | c.456C>T p.I152= | Silent (SNP) | VAF 28/396 reads (7%) | catalogued as COSV100071075; called by muse, mutect2
- GHSR | c.117C>T p.P39= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs776496820, COSV53840268; called by muse, mutect2, varscan2
- IBSP | c.495C>T p.S165= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs200405481, COSV56896722; called by muse, mutect2, varscan2
- IFT122 | c.489C>T p.G163= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs750993030, COSV99959559; called by muse, mutect2, varscan2
- IQCG | c.363G>A p.P121= | Silent (SNP) | VAF 86/391 reads (22%) | catalogued as rs1256911194, COSV54560140; called by muse, mutect2, varscan2
- IQGAP1 | c.4107C>T p.F1369= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs368968167, COSV51581696; called by muse, mutect2, varscan2
- KCNH2 | c.1635C>T p.Y545= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs200692436, COSV100059893; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- KIF22 | c.1968C>G p.L656= | Silent (SNP) | VAF 39/258 reads (15%) | catalogued as COSV99361307; called by muse, mutect2, varscan2
- LATS2 | c.2862C>T p.S954= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs749648130, COSV66880202; called by muse, mutect2, varscan2
- LRRC8A | c.810C>T p.I270= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV99396736; called by muse, mutect2, varscan2
- MAB21L1 | c.672G>A p.S224= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs577985182, COSV100082155; called by muse, mutect2, varscan2
- MDGA2 | c.1995C>T p.Y665= (on ENST00000399232 / NM_001113498.2; = p.Y367= on NM_182830.4) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs368219229, COSV62081391; called by muse, mutect2, varscan2
- MOK | c.145C>A p.R49= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99513345; called by muse, mutect2, varscan2
- MYH6 | c.4840C>T p.L1614= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV100676785; called by muse, mutect2, varscan2
- NOL10 | c.2031G>A p.L677= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as COSV62041981; called by muse, mutect2, varscan2
- NR0B1 | c.1035G>T p.P345= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100973549, COSV66764143; called by muse, mutect2, varscan2
- PAFAH2 | c.744G>A p.K248= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1211491651, COSV100959332; called by muse, mutect2, varscan2
- PHACTR1 | c.711G>A p.S237= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs369125089; called by muse, mutect2, varscan2
- PTPN12 | c.1110C>G p.P370= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99950511; called by muse, mutect2, varscan2
- PWWP2B | c.1515G>A p.P505= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs762175356, COSV100535878; called by muse, mutect2, varscan2
- RANBP2 | c.9229C>T p.L3077= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as COSV99312662; called by muse, mutect2, varscan2
- RHOA | c.75C>T p.F25= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs147354494; called by muse, mutect2
- RRNAD1 | c.894G>A p.L298= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs759567108, COSV100836968; called by muse, mutect2, varscan2
- S100A13 | c.99C>T p.L33= | Silent (SNP) | VAF 33/219 reads (15%) | catalogued as COSV52681486; called by muse, mutect2, varscan2
- SLC13A4 | c.1036C>T p.L346= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV62460733; called by muse, mutect2, varscan2
- SLC2A12 | c.1710G>A p.V570= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV51601251; called by muse, mutect2, varscan2
- SLC4A5 | c.261C>T p.I87= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs764913119, COSV100697824; called by muse, mutect2, varscan2
- SORCS1 | c.324G>A p.R108= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99548111; called by muse, mutect2, varscan2
- SPATA31E1 | c.618G>A p.P206= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs576230052, COSV100350722; called by muse, mutect2, varscan2
- TAF5 | c.756C>T p.V252= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100674723; called by muse, mutect2, varscan2
- THPO | c.990C>G p.L330= (on ENST00000649095 / NM_001290003.1; = p.L190= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV52617354, COSV99201207; called by muse, mutect2, varscan2
- TMED4 | c.618C>T p.L206= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV56942711; called by muse, mutect2, varscan2
- TOMM20 | c.21C>T p.A7= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as rs771030402, COSV100784000; called by muse, mutect2, varscan2
- UFL1 | c.2094C>G p.T698= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100990102; called by muse, mutect2, varscan2
- ZNF385A | c.810C>T p.V270= (on ENST00000338010 / NM_001130967.3; = p.V250= on NM_015481.3) | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV100566941; called by muse, mutect2, varscan2
- BTNL8 | c.787+130dup | Intron (INS) | VAF 30/237 reads (13%) | called by mutect2, pindel, varscan2
- KIAA0895L | c.*2G>A | 3'UTR (SNP) | VAF 13/97 reads (13%) | catalogued as COSV99220568; called by muse, mutect2, varscan2
